FM case AD13972 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/3cb62ff9-21d3-4dae-8a36-c0d9ebf4b0e9

Male, 52.2 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the bladder; primary biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
